Gene-level copy-number profile of tumor specimen TCGA-04-1517-01A from TCGA case TCGA-04-1517, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.5 years (29,045 days).
Specimen TCGA-04-1517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5e521fd3-5489-4e99-92db-70c6bb30d44f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1517-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8037327e-2034-40a6-8e29-79479bdf8976

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,328; copy number 2: 20,762; copy number 3: 15,738; copy number 4: 12,619; copy number 5: 3,984; copy number 6: 4,047; copy number 7: 278; copy number 8: 40; copy number 10: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1517-01): tumor purity 0.83, ploidy 6.95, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,680,088–42,827,617, 6 genes: AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,353 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,866,284–94,411,036, 18 genes, copy number 5 (within-gene range 4–5): DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1.
- chr1:117,143,587–117,528,872, 5 genes, copy number 5 (within-gene range 4–5): VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2.
- chr1:150,794,880–151,459,494, 42 genes, copy number 5 (within-gene range 4–5): CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25.
- chr1:155,659,443–156,212,796, 28 genes, copy number 5 (within-gene range 4–5): YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44.
- chr1:156,212,993–156,240,042, 1 gene, copy number 5 (within-gene range 3–5): PMF1.
- chr1:180,632,022–180,890,279, 2 genes, copy number 5 (within-gene range 3–5): XPR1, U6.
- chr1:224,802,959–248,919,946, 599 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:46,293,667–46,394,228, 2 genes, copy number 5: EPAS1, LINC01820.
- chr2:149,320,593–149,321,436, 1 gene, copy number 6: FAM8A3P.
- chr2:176,506,245–176,612,249, 4 genes, copy number 6: AC017048.1, AC017048.2, MIR1246, AC017048.3.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–10 (broad region; genes not listed).
- chr5:2,712,591–5,140,119, 30 genes, copy number 5: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2.
- chr5:17,684,584–31,595,669, 125 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:165,129,307–167,168,401, 12 genes, copy number 5: AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1.
- chr5:167,287,320–167,660,481, 4 genes, copy number 5: AC091820.2, AC091820.1, AC008601.1, AC008708.2.
- chr6:6,450,356–6,918,715, 11 genes, copy number 5 (within-gene range 3–5): AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1.
- chr6:42,499,710–42,903,072, 10 genes, copy number 5: AL591473.1, UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, AL035587.3.
- chr6:43,243,481–43,737,834, 30 genes, copy number 5 (within-gene range 3–5): TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2.
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:100,133,351–100,663,415, 17 genes, copy number 6 (within-gene range 4–6): FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1.
- chr9:4,299,390–4,386,556, 2 genes, copy number 5: AL162419.1, RNU6-694P.
- chr10:59,650,761–59,960,913, 4 genes, copy number 5–7 (within-gene range 4–7): SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,050,668–60,081,854, 2 genes, copy number 5: AL592430.1, Y_RNA.
- chr12:9,448,295–27,695,564, 364 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:95,551,582–95,673,999, 2 genes, copy number 5 (within-gene range 3–5): PGAM1P5, Y_RNA.
- chr14:32,329,298–32,837,684, 1 gene, copy number 5 (within-gene range 3–5): AKAP6.
- chr14:32,484,098–32,484,800, 1 gene, copy number 5: MTCO1P2.
- chr14:50,632,058–50,865,659, 10 genes, copy number 6 (within-gene range 3–6): SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1.
- chr14:64,986,895–65,062,652, 1 gene, copy number 6 (within-gene range 3–6): FNTB.
- chr14:65,006,174–65,335,183, 11 genes, copy number 6 (within-gene range 3–6): MAX, MIR4706, AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708.
- chr14:65,411,170–65,529,574, 4 genes, copy number 6: FUT8-AS1, RPL21P8, MIR625, EIF1AXP2.
- chr14:67,819,779–68,730,218, 7 genes, copy number 6 (within-gene range 3–6): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr14:83,750,384–87,872,291, 30 genes, copy number 5 (within-gene range 3–5): RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1.
- chr14:103,148,597–103,562,831, 21 genes, copy number 6 (within-gene range 4–6): RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5.
- chr17:49,887,598–50,181,178, 20 genes, copy number 5 (within-gene range 2–5): AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P.
- chr17:78,130,770–78,225,636, 8 genes, copy number 5 (within-gene range 2–5): TMC8, C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 5–8 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 6 (broad region; genes not listed).
- chr22:29,767,091–30,574,665, 39 genes, copy number 6 (within-gene range 3–6): AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1.
- chr22:37,570,248–37,582,616, 2 genes, copy number 6: LGALS2, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 2,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
